Surgical pathology report (de-identified scan), TCGA case TCGA-09-1675, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1675-01B (Primary Tumor).

[page 1 of 10]
Specimen(s) Received

A: Anterior abdominal wall nodule, fs

H&E, First x 1

B: Left adnexal mass, ovary, fs

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

C: Omentum, biopsy, fs

H&E, First x 1, H&E, First x 1, H&E, First x 1

D: Uterus

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1

E: Omentum, resection

H&E, First x 1

F: small bowel adhesion #1

H&E, First x 1

G: left common iliac lymph nodes, resection

H&E, First x 1

H: Fallopian tube, tumor, left

H&E, First x 1

I: Appendix, incidental

H&E, First x 1

J: Ovary, cvs, left, wall

H&E, First x 1

K: Lymph nodes, regional resection, left pelvic

H&E, First x 1, H&E, First x 1, H&E, First x 1

Final Pathologic Diagnosis:

A. Soft tissue, anterior abdominal wall, biopsy: Fibrous tissue with scarring and hemosiderin deposition; no carcinoma or endometriosis identified.

B. Left ovary, mass, excision:

1. Papillary serous cystadenocarcinoma, moderately differentiated; see comment.

2. Residual atrophic ovarian tissue with remote hemorrhage.

Page 1 of 10

C. Omentum, biopsy: Scar, histiocytic reaction, and hemosiderin, consistent with fat necrosis.

D. Uterus, supracervical hysterectomy:

-Endocervix: No significant pathologic abnormality.

-Endometrium: Weakly proliferative pattern with focal cystic atrophy.

-Myometrium: Leiomyoma.

E. Omentum, resection: Scar, histiocytic reaction, and hemosiderin, consistent with fat necrosis.

[page 2 of 10]
[REDACTED]

F. Small bowel, adhesion, biopsy: Histiocytic infiltrate, consistent with reaction to fat necrosis.

G. Lymph nodes, left common iliac, excision: Two lymph nodes with no tumor seen (0/2).

H. Left fallopian tube, salpingectomy:

1. Fallopian tube with benign paratubal cysts.
2. Rare changes consistent with endometriosis.

I. Appendix, incidental appendectomy: Focal inclusions consistent with endometriosis.

J. Left ovary, "cyst wall," biopsy: Ovarian tissue with no significant pathologic abnormality.

K. Lymph nodes, left pelvic, regional resection: Seven lymph nodes with no tumor seen (0/7).

Note:

Ovarian Tumor Synoptic Comment

1. Type of tumor: Serous cystadenocarcinoma.

2. Grade of tumor: II.

3. Location of tumor: Unilateral, left ovary.

4. Diameter of tumor: 10.0 cm maximum dimension.

5. Appearance of surface of ovary: Tumor on surface.

6. Condition of capsule: Intact.

7. Appearance of cut surface: Solid and cystic, mainly cystic.

8. Color of solid areas: White.

9. Necrosis: Focally present.

10. Lymphatic/vascular invasion: Not present.

11. Sites of metastases in pelvis: None.

12. Pelvic lymph nodes: None contain metastatic tumor (0/7).

13. Sites of metastases in abdomen: None.

14. Para-aortic lymph nodes: None of the left common iliac nodes contain tumor (0/2).

15. Peritoneal cytology: Benign [REDACTED]

16. Other significant findings: Fat necrosis in the omental specimens and inclusions consistent with endometriosis in the left fallopian tube and appendectomy specimens.

17. FIGO stage: IC.

18. TNM stage: pT1cN0Mx.

19. Additional Comments: The tumor is characterized by numerous papillary structures with occasional micropapillary foci. Focally, there is solid tumor. This histologic appearance is that of a primary papillary

Page 2 of 10

serous cystadenocarcinoma of the ovary. This pattern would not be seen in a metastasis from a breast primary.

Intraoperative Consult Diagnosis

FS1 (A) Anterior abdominal wall nodule, biopsy: Fibrous tissue with scarring and hemosiderin deposition, no carcinoma or endometriosis identified. [REDACTED]

FS2 (B) Left adnexal mass, biopsy: Papillary adenocarcinoma. [REDACTED]

FS3 (C) Omentum, biopsy: Fibrohistiocytic nodule, no tumor seen [REDACTED]

Clinical History

The patient is a [REDACTED] with a complex left adnexal mass. [REDACTED] has a history of two liver transplants for primary biliary cirrhosis as well as a history of [REDACTED] and right salpingo-oophorectomy for endometriosis. [REDACTED] current CA-125 level is 15. [REDACTED] now undergoes

[page 3 of 10]
[REDACTED]

supracervical hysterectomy, left salpingo-oophorectomy, lymph node dissection, omentectomy and appendectomy.

Gross Description

The specimen is received fresh in eleven parts, each labeled with the patient's name and medical record number.

Part A, designated "anterior abdominal wall nodule," consists of a 1.2 x 1.2 x 1.0 cm, soft, tan-red nodule. The specimen is entirely used for frozen section #1 and then re-submitted in cassette A1.

Part B, designated "left adnexal mass," consists of a 10.0 x 8.0 x 4.0 cm cyst with chocolate-colored fluid contents, weighing 245 gm. Upon opening the cyst, there is a 4.0 x 3.0 x 2.0 cm, whitish tan, papillary mass extending from the internal surface of the cyst through the wall and involving the external surface of the cyst. The external surface of the cyst wall is inked in black. A representative section of the papillary mass is taken for frozen section in cassettes B1-B4. Sections of uninvolved cyst wall are submitted in cassette B5. An adjacent portion shows 1.5 cm of ovarian tissue with a central cyst; this is submitted in cassette B6.

Part C, designated "omentum," consists of a 1.5 x 1.0 x 0.8 cm mass of tan to pink to yellow, soft fibroadipose tissue. A representative section is used for frozen section diagnosis # 3 and then re-submitted

in cassette C1. The remainder of the specimen is submitted in entirety in cassettes C2-3.

Part D, designated "uterus," consists of a 6.0 x 4.0 x 4.0 cm supracervical hysterectomy specimen with extensive cautery artifact of the serosal surface. The cervical os is difficult to distinguish. The cervical neck margin is submitted in cassette D1. The lower uterine segment shows extensive cautery artifact. Representative sections of lower uterine segment are submitted in cassette D2. The myometrium shows an

intramural, 1.0-cm leiomyoma. Representative sections are submitted in cassette D3. The endometrium is grossly unremarkable. A representative section is submitted in cassette D4.

Part E is identified as "omentum," and consists of a sheet of yellow fat (15 x 8 x 1.5 cm) containing a single

1-cm, firm, oval mass with a cystic solid yellow-tan cut surface. Representative sections are submitted in cassette E1.

Part F, identified as "small bowel adhesion," consists of an unoriented, firm, tan-gray fragment, 0.9 cm in greatest dimension. It is entirely submitted in cassette F1.

Part G, identified as "left common iliac node," consists of an irregular, oval, tan-gray fragment with a small

amount of fibroadipose tissue measuring 2.0 cm in greatest dimension. The specimen is bisected and submitted in entirety in G1.

Part H, identified as "left tube," consists of a 4-cm, purple-gray cylinder with a 0.5-cm average cross section

attached to unremarkable yellow fat. A representative section is submitted in cassette H1.

Part I, identified as "appendix," consists of a 3.5-cm-long, tan-white appendix with an average diameter of 0.8 cm. The serosal surfaces are smooth and serial cross-sections are unremarkable. Representative sections are submitted in cassette I1.

Page 3 of 10

Part J, identified as "left ovarian cyst wall," consists of an unoriented, fibrous, tan-yellow-gray, variegated fragment 2.0 cm in greatest dimension. It is bisected and entirely submitted in cassette J1.

Part K, identified as "left pelvic lymph node," consists of several tan-yellow candidate lymph nodes with greatest dimensions of up to 2 cm accompanied by unremarkable yellow fat. Representative sections are submitted in cassettes K1-K3.

Part I dictation incomplete?

[REDACTED]

[page 4 of 10]
[REDACTED]

Other Specimens

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Transplant liver, biopsy:

1. No evidence of acute or chronic rejection.
2. Mild non-specific changes; see comment.
- [REDACTED]

[REDACTED]

Specimen(s) Received: Bronchial Washing (Organisms)

Final Diagnosis

Bronchial Washing (Organisms)

BENIGN.

(Negative for cytomegalovirus.

Negative for Pneumocystis

No fungus identified.

[REDACTED]

[REDACTED]

Signed Out:

Other Case Number(s): [REDACTED]

Specimen(s) Received: Bone marrow, clot, left

Final Diagnosis {Final Report Not Signed Out}

{Not Entered}

[REDACTED]

[REDACTED]

Specimen(s) Received: A: BM Aspirate Clot -left, B: BM Aspirate Smear - It, C: BM Peripheral Smear

Final Diagnosis

1. Normocellular bone marrow with mixed hematopoiesis.
2. No evidence of a lymphoproliferative disorder; see comment.
3. No metastatic tumor identified; see comment.
- [REDACTED]

[page 5 of 10]
[REDACTED]

[REDACTED]

Specimen(s) Received: Left temporal lesion- fs

Final Diagnosis

Brain, left temporal lobe, biopsy: High-grade B-cell malignancy, favor Diffuse Large B-cell Lymphoma; see comment.

[REDACTED]

Addendum Comment

The Epstein-Barr Virus in situ hybridization stain is strongly positive in numerous nuclei.

[REDACTED]

Specimen(s) Received: Cerebrospinal Fluid

Final Diagnosis

Cerebrospinal Fluid

BENIGN.

[REDACTED]

Specimen(s) Received: Pelvic washing

Final Diagnosis

Pelvic Washing

BENIGN.

Red cells predominate and dilute the specimen.

[REDACTED]

[REDACTED]

[REDACTED]

Specimen(s) Received: A: Hernia sac, B: Liver transplant biopsy

Final Diagnosis

A. Soft tissue, abdomen, herniorrhaphy: Hernia sac.

B. Transplant liver, biopsy:

1. Focal mild portal inflammation; see comment.

2. No evidence of rejection.

3. Minimal fatty change (<5%).

[page 6 of 10]
[REDACTED]

[REDACTED]

Specimen(s) Received: A: LT chest wall, B: RT chest wall

Final Diagnosis

A. Chest wall, left, excision: Skin and adipose tissue, no significant pathologic abnormality, no tumor identified.

B. Chest wall, right, excision: Skin and adipose tissue, no significant pathologic abnormality, no tumor identified.

[REDACTED]

[REDACTED]

Specimen(s) Received: Cervical, Thin Prep

Final Diagnosis

Cervical, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Transformation zone components are present.

[REDACTED]

[REDACTED]

Specimen(s) Received: Cervical, Thin Prep

Final Diagnosis

Cervical, Thin Prep

CELLULAR CHANGES WITHIN NORMAL LIMITS.

Atrophic pattern

SPECIMEN ADEQUACY:

Page 6 of 10

Satisfactory for evaluation. Endocervical cells present.

[REDACTED]

[REDACTED]

Specimen(s) Received: Peritoneal Washing

Final Diagnosis

Peritoneal Washing

BENIGN.

[REDACTED]

[page 7 of 10]
[REDACTED]

Specimen(s) Received: Fine Needle Aspirate, Other, Deep, Spleen

Final Diagnosis

Spleen, fine needle aspirate: **Extramedullary hematopoiesis.** See comment.

[REDACTED]

[REDACTED]

Specimen(s) Received: Lymph Node, Fine Needle Aspiration

Final Diagnosis

Periportal Lymph Node, Fine Needle Aspiration: **Metastatic adenocarcinoma, see note.**

[REDACTED]

[REDACTED]

Specimen(s) Received: Common Bile Duct

Final Diagnosis

Common Bile Duct

BENIGN.

Fungi.

[REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Liver, transplant biopsy: Prominent cholestasis with bile duct injury and focal portal inflammation, consistent with resolving rejection and possible obstruction; see comment.

[REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Liver, transplant biopsy:

1. Mild rejection

[page 8 of 10]
[REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Liver, transplant biopsy: Moderate acute cellular rejection.

[REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Liver transplant, biopsy:

- 1. Centrilobular cholestasis c/w residual preservation injury**, see comment.
- 2. No evidence of acute cellular rejection.**
- [REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Liver transplant, biopsy:

1. Focal pericholangitis, see comment.
2. Mild preservation injury with cholestasis.
- [REDACTED]

[REDACTED]

Specimen(s) Received: Liver, hepatectomy

Final Diagnosis

Liver, hepatectomy: Chronic transplant rejection, vascular type with focally severe ductal injury consistent with evolving chronic ductopenic rejection.

[REDACTED]

[REDACTED]

Specimen(s) Received: A: Liver transplant, biopsy, B: Liver transplant, biopsy, fs

Final Diagnosis

Liver transplant, biopsy: Chronic rejection with severe cholestasis; see comment.

[REDACTED]

[page 9 of 10]
[REDACTED]

Specimen(s) Received: Consult with slides only

Final Diagnosis

Review of Outside Material, [REDACTED]

Breast, right, biopsy of mass [REDACTED] Poorly differentiated infiltrating ductal carcinoma, see comment.

[REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Transplant liver, biopsy:

- 1. Focal duct damage in portal zones.**
- 2. Centrilobular hepatocyte necrosis. See comment.**
- [REDACTED]

[REDACTED]

Specimen(s) Received: Liver transplant, biopsy

Final Diagnosis

Transplant liver, biopsy:

1. Mixed portal infiltrate with duct damage - favor acute cellular rejection, see comment.
2. Parenchymal inflammatory infiltrate, see comment.
- [REDACTED]

[REDACTED]

Specimen(s) Received: LIVER TXP

Final Diagnosis

TRANSPLANT LIVER, BIOPSY:

1. MILD CENTRIOLOBULAR FATTY CHANGE.
2. NO EVIDENCE OF REJECTION.

Conversion

[REDACTED]

[REDACTED]

Specimen(s) Received: TRANSPLANT LIVER

Final Diagnosis

LIVER, PERCUTANEOUS BIOPSY:

1. NO EVIDENCE OF REJECTION.
2. NONSPECIFIC CHANGES. SEE NOTE.

[page 10 of 10]
[REDACTED]

Specimen(s) Received: LIVER TXP

Page 9 of 10

Final Diagnosis

LIVER, BIOPSY: MILD NONSPECIFIC PORTAL INFLAMMATION; NO EVIDENCE OF ACUTE REJECTION.
Conversion

[REDACTED]

[REDACTED]

Specimen(s) Received: LIVER TXP

Final Diagnosis

TRANSPLANT LIVER, BIOPSY: MILD PORTAL INFLAMMATION CONSISTENT WITH RESOLVING REJECTION,
SEE
NOTE.

[REDACTED]

[REDACTED]

Specimen(s) Received: LIVER TX

Final Diagnosis

TRANSPLANT LIVER, BIOPSY: ACUTE TRANSPLANT REJECTION (MILD-MODERATE), NOT SIGNIFICANTLY
IMPROVED FROM THE PREVIOUS BIOPSY [REDACTED] SEE NOTE.

[REDACTED]

[REDACTED]

Specimen(s) Received: LIVER TXP

Final Diagnosis

LIVER, TRANSPLANT BIOPSY:
1. MILD-TO-MODERATE ACUTE REJECTION.
2. MILD PRESERVATION INJURY.

[REDACTED]

[REDACTED]

Specimen(s) Received: LIVER

Final Diagnosis

LIVER, EXPLANT: BRIDGING FIBROSIS WITH FOCI OF CIRRHOSIS AND CHANGES COMPATIBLE WITH
PRIMARY
BILIARY CIRRHOSIS. SEE NOTE.
Conversion

[REDACTED]

Source: NCI Genomic Data Commons file 8cf8ae6e-f35b-4551-a45f-514de1e048fb (TCGA-09-1675.F981F103-FC2D-4F41-9F71-015F194391F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).